Somatic mutation profile of tumor specimen TARGET-30-PAKYZS-01A (aliquot TARGET-30-PAKYZS-01A-01W) from TARGET case TARGET-30-PAKYZS, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 1.8 years (659 days).
Specimen TARGET-30-PAKYZS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4adc833-7cb6-4aa5-aa20-167bf363d9d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKYZS-10A (Blood Derived Normal), aliquot TARGET-30-PAKYZS-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76bf0fe0-8189-4866-a169-21184b8e8f30

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MOGAT3 | c.403T>C p.S135P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- KNTC1 | c.4015T>C p.L1339= | Silent (SNP) | VAF 30/476 reads (6%) | called by muse, mutect2
- PKDREJ | c.4806C>T p.Y1602= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as rs1265653127; called by muse, mutect2
